Somatic mutation profile of tumor specimen TCGA-EM-A2OX-01A (aliquot TCGA-EM-A2OX-01A-11D-A202-08) from TCGA case TCGA-EM-A2OX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 46.3 years (16,911 days).
Specimen TCGA-EM-A2OX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11bffeb0-9890-4fab-882b-70f90d4b45e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2OX-10A (Blood Derived Normal), aliquot TCGA-EM-A2OX-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e58071dd-a8fd-4a63-83e2-7856aa22f7e8

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACD | c.875A>G p.H292R (on ENST00000620338; = p.H203R on NM_022914.3) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54669826; called by muse, mutect2, varscan2
- ANKRD30A | c.2006A>T p.E669V (on ENST00000611781; = p.E613V on NM_052997.2) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV64618307; called by muse, mutect2, varscan2
- HRH2 | c.464A>T p.H155L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV51575713; called by muse, mutect2, varscan2
- ZNF117 | c.1132A>G p.T378A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV51429417; called by muse, mutect2, varscan2
- CHUK | c.2013A>G p.L671= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV64918556; called by muse, mutect2, varscan2
- ITGAX | c.1663C>T p.L555= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as COSV51650094; called by muse, mutect2, varscan2
- JAK2 | c.303C>T p.V101= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV67653332; called by muse, mutect2, varscan2
- ROS1 | c.5055C>T p.I1685= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100877262; called by muse, varscan2
- ABL2 | c.158-9632T>C | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as rs1326680522, COSV61019427; called by muse, mutect2, varscan2
